Surgical pathology report (de-identified scan), TCGA case TCGA-BL-A13I, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BL-A13I-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Urothelial Carcinoma, NOS 81201

for
11/16/10

Site: bladder, NOS c67.9

SPECIMEN

- A. Right ureter
- B. Left ureter
- C. Urethral margin
- D. Bladder, uterus, bilateral tubes and ovaries.
- E. Left pelvic node
- F. Right pelvic node
- G. Appendix

CLINICAL NOTES

CLINICAL HISTORY: Bladder cancer.

FROZEN SECTION DIAGNOSIS

- A. Right ureter, margin: Negative for malignancy.
- B. Left ureter, margin: Negative for malignancy.
- C) Urethral margin, biopsy: Negative for malignancy.

GROSS DESCRIPTION

- A. The specimen is received fresh for frozen section labeled "A - right ureter" and consists of a 0.4 cm in diameter, 0.3 cm in length, piece of tubular tan tissue with a pinpoint lumen. The specimen is entirely frozen as frozen section. AFS-1.
- B. Received fresh for frozen section labeled "B - left ureter" is a 0.3 x 0.3 x 0.2 cm piece of tubular tan tissue with a pinpoint lumen. The specimen is entirely frozen as frozen section
- C. The specimen is received unfixed labeled "urethral margin" and consists of a piece of pink soft tissue measuring 1.2 x 1 x 0.2 cm. The specimen is dissected and submitted for frozen section diagnosis.
- D. The specimen is received unfixed labeled "bladder, uterus, bilateral tubes and ovaries" and consists of a

GROSS DESCRIPTION

urinary bladder with attached uterus and bilateral adnexa. The uterus measures 7 x 4 x 2 cm. The right ovary is tan-white and measures 4.2 x 1 x 0.2 cm. Right uterine tube is pink and measures

[page 2 of 4]
7 cm. in length and 0.3 cm. in diameter. The left ovary is tan-white and measures 3.5 x 1 x 0.4 cm. The left uterine tube is purple to pink and measures 8 cm. in length and 0.3 cm. in diameter. The ectocervix is white and measures 2.7 x 3 cm. The external os measures 0.2 x <0.1 cm. There is an adjacent cuff of vaginal tissue measuring 6 x 3.5 cm. The urethra is identified and is inked. The bladder is opened without inflation for tissue procurement. There is a red tumor measuring approximately 2 x 1.2 x 2 cm. The tumor is in the superior posterior right side of the specimen. There is stenosis of the internal os. The uterine cavity is not well seen on initial sectioning. There is a polyp in the high endocervical canal measuring 1 cm. x 0.5 x 0.3 cm. Sections after fixation.

Block summary: D1 left ovary; D2 left uterine tube; D3 right ovary; D4 right uterine tube; D5, D6 vaginal cuff; D7, D8 uterine cervix; D9, D10 endocervical polyp; D11, D12 endomyometrium; D13-D16 bladder tumor; D17 right trigone; D. 18 right bladder wall up to tumor; D19 left trigone; D20 left bladder wall; D 21 dome of bladder; D22 right side of bladder; D23 left side of bladder; D 24-D26. Perivesicle fat

E. Received unfixed labeled "left pelvic nodes" and consists of multiple pieces of yellow soft tissue measuring 4.5 x 4.5 x 1.5 cm. Sections after fixation.
F. Received unfixed labeled "right pelvic node" and consists of white pelvic nodes and consists of multiple pieces of yellow and red soft tissue measuring 3 x 2.5 x 1.4 cm. Sections after fixation.
G. Received in formalin labeled "appendix" and consists of a thin white vermiform appendix measuring 5.2 cm. in length

GROSS DESCRIPTION

and 0.3 cm. in diameter. There is an attached mesoappendix measuring 2 x 4.5 x 1 cm. No serosal exudate is seen.

[page 3 of 4]
MICROSCOPIC DESCRIPTION

- A. Sections of the right ureter negative for malignancy
- B. Sections of the left ureter negative for malignancy
- C. Sections of the urethral margin are negative for malignancy
- D.

The patient's tumor is unusually high grade. Since the surrounding bladder is relatively normal appearing, the possibility of a metastasis was considered - including metastatic melanoma.

Immunostains show no keratin staining. There is weak MART-1 staining of uncertain significance, but HMB-45 is negative. S-100 is equivocal with possible focal tumor cell staining. The immunostain results are equivocal; in the absence of any history of another tumor, the tumor probably represents a high grade

urothelial
cell carcinoma.

Tumor grade: 4 (out of 4), WHO grade: High grade

Tumor size: 2 cm

Mitotic rate: 30 mitoses/10 HPFs (1 HPF = 0.196 sq mm)

Multicentricity: Absent

Depth of invasion: Carcinoma invades through the muscularis propria into perivesical soft tissue

Vascular invasion: Absent

Perineural invasion: Absent

Ureteral margins: Negative for malignancy

Urethral margin: Negative for malignancy

Adjacent bladder mucosa: Unremarkable

pTNM Stage: T3 N0

MICROSCOPIC DESCRIPTION

Sections of the uterus show benign endocervical polyp and other otherwise unremarkable. Sections of the ovaries and uterine tubes are unremarkable. The vaginal cuff is unremarkable.

Antibody	Results	Comment
----------	---------	---------

AE1-AE3	Negative	
CK7	Negative	
CK20	Negative	
EMA	Negative	
MART1	Weakly positive	
HMB-45	Negative	
S-100	Equivocal	

Paraffin sections; 10% neutral buffered formalin

[page 4 of 4]
[A few of the antibodies used in our laboratory may be classified as

analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

- D. There is no evidence of malignancy in any of 7 lymph nodes
- F. There is no evidence of malignancy in any of 5 lymph nodes
- G. Sections of appendix show fibrous obliteration of the appendiceal lumen.

3x3, 2, 5, 4x2 , 20x7

DIAGNOSIS

- A. Ureter, right, biopsy: Negative for malignancy
- B. Ureter, left, biopsy: Negative for malignancy
- C. Urethral margin, biopsy: Negative for malignancy

- D. Bladder, uterus and bilateral adnexa, resection:

Urinary bladder: Poorly differentiated malignant tumor (see micro)

microscopic status

Uterine cervix: Benign endocervical polyp

w. atypical

Endometrium: Inactive-type endometrium

cell carcinoma

Myometrium: No pathological diagnosis

Ovaries, left and right: No pathological diagnosis

Uterine tubes, left and right: No pathological diagnosis

- E. Lymph nodes, left pelvic biopsy:

There is no evidence of malignancy in any of 7 lymph nodes

- F. Lymph nodes, right pelvic, biopsy:

There is no evidence of malignancy in any of 5 lymph nodes

- G. Vermiform appendix, resection: Negative for malignancy.

(Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file f8c0ecc7-4d3a-4192-81be-2969fee9cad2 (TCGA-BL-A13I.976FBDBF-55C5-4957-986B-D2DE85FF7540.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).